Somatic mutation profile of tumor specimen TCGA-B8-A7U6-01A (aliquot TCGA-B8-A7U6-01A-12D-A36X-10) from TCGA case TCGA-B8-A7U6, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.2 years (19,803 days).
Specimen TCGA-B8-A7U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90736cc1-184e-41e6-a705-4b28daf597f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A7U6-10A (Blood Derived Normal), aliquot TCGA-B8-A7U6-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1038e290-f315-40f3-9b91-f813d4c3acfa

The open-access MAF lists 70 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Frame Shift Del 5, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, Intron 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.2581A>G p.N861D | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV100419250; called by muse, mutect2, varscan2
- ALPK2 | c.402A>C p.E134D | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV100864477; called by muse, mutect2
- ANP32D | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874332; called by muse, mutect2
- APOL2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1286886718, COSV99969161; called by muse, mutect2
- ARHGAP35 | c.1918A>T p.I640L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV101351216, COSV68334908; called by muse, mutect2, varscan2
- ASCC3 | c.1976C>G p.T659R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763808185, COSV100225895; called by muse, mutect2, varscan2
- BTBD16 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99584942; called by muse, mutect2, varscan2
- CAMLG | c.570A>G p.I190M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99777775; called by muse, mutect2, varscan2
- CEP128 | c.2199C>G p.I733M | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1243565216, COSV99825028; called by muse, mutect2
- CLEC4F | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV99713791; called by muse, mutect2, varscan2
- CSMD1 | c.10284G>T p.K3428N (on ENST00000520002; = p.K3427N on NM_033225.6) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100149512; called by muse, mutect2
- CXCL14 | c.318C>T p.R106= (on ENST00000337225; = p.R94= on NM_004887.5) | Splice Region (SNP) | VAF 25/100 reads (25%) | catalogued as rs976783688, COSV100463647; called by muse, mutect2, varscan2
- CYP2W1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.352); catalogued as rs1351878570, COSV100417219; called by muse, mutect2
- DEFB112 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.915); catalogued as COSV59182927; called by muse, mutect2, varscan2
- DENND6A | c.426C>G p.Y142* | Nonsense Mutation (SNP) | VAF 75/200 reads (38%) | catalogued as COSV100231537; called by muse, mutect2, varscan2
- GMIP | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99179330; called by muse, mutect2, varscan2
- GRID2 | c.324G>C p.L108F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99942125; called by muse, mutect2, varscan2
- HEXD | c.1204A>T p.K402* (on ENST00000327949 / NM_001369487.1; = p.G431= on NM_173620.3) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100027786; called by muse, mutect2, varscan2
- HOXC13 | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99078875, COSV99673438; called by muse, varscan2
- HYDIN | c.12116A>C p.E4039A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as COSV101125113; called by muse, mutect2, varscan2
- IL2RG | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs762171617, COSV99340315; called by muse, mutect2, varscan2
- ISLR | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99997391; called by muse, mutect2, varscan2
- KCTD10 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949318; called by muse, mutect2, varscan2
- LRR1 | c.219T>A p.F73L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100023171; called by muse, mutect2, varscan2
- MS4A2 | c.210G>C p.M70I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV54011848, COSV99627363; called by muse, mutect2, varscan2
- NOXO1 | c.278G>A p.G93D (on ENST00000397280 / NM_172168.3; = p.G87D on NM_144603.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as rs763912614, COSV99937057; called by muse, mutect2, varscan2
- OLFM4 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as rs541581446, COSV99524401; called by muse, mutect2
- OVOL2 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99602494; called by muse, mutect2, varscan2
- PCDHGB3 | c.1826T>C p.V609A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV99540411; called by muse, mutect2
- PITPNM2 | c.2997+1G>A p.X999_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99759171; called by muse, mutect2
- POLE | c.3359A>C p.Q1120P | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1565953982, COSV100267131; ClinVar: uncertain significance; called by muse, mutect2
- PRKDC | c.6860C>G p.P2287R | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100041109, COSV58054732; called by muse, mutect2, varscan2
- RANBP3 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99222350; called by muse, mutect2
- SARM1 | c.1507T>A p.Y503N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99135009; called by muse, mutect2, varscan2
- SCAF8 | c.1625A>T p.K542M | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100914140; called by muse, mutect2, varscan2
- SORL1 | c.6314A>G p.N2105S | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99494261; called by muse, mutect2
- STAT3 | c.2174C>T p.P725L (on ENST00000264657 / NM_001369512.1; = p.P724L on NM_003150.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769372865, COSV99232866; called by muse, mutect2
- SYTL4 | c.1084T>G p.F362V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV52167419, COSV99342994; called by muse, mutect2
- TEKT4 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1483443448, COSV99726436; called by muse, mutect2
- TET1 | c.1316C>A p.P439Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV101018427; called by muse, mutect2, varscan2
- TRPM6 | c.4415G>C p.W1472S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.081); catalogued as COSV100666537; called by muse, mutect2
- TRPS1 | c.302C>T p.P101L (on ENST00000220888 / NM_001330599.2; = p.P114L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1196741344, COSV55236510; called by muse, mutect2, varscan2
- TTN | c.24167T>C p.L8056P (on ENST00000591111; = p.L7129P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | PolyPhen possibly damaging (0.633); catalogued as COSV100617891; called by muse, mutect2, varscan2
- UHRF1BP1L | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99691766; called by muse, mutect2, varscan2
- ZC3H7B | c.2178G>C p.K726N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100687436; called by muse, mutect2
- ZFC3H1 | c.4754A>C p.K1585T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV101110596; called by muse, mutect2, varscan2
- ZIC5 | c.1681T>C p.S561P | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940635; called by muse, mutect2
- ZNF85 | c.594A>C p.R198S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.216); catalogued as COSV100059896; called by muse, mutect2, varscan2
- ZSCAN5B | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs775303355, COSV62000658; called by muse, mutect2, varscan2
- ABCA1 | c.891del p.T298Pfs*20 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, varscan2
- LAMA3 | c.6655del p.L2219* (on ENST00000313654 / NM_198129.4; = p.L610* on NM_000227.6) | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- MAB21L2 | c.395del p.F132Sfs*20 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- NALCN | c.506del p.N169Ifs*3 | Frame Shift Del (DEL) | VAF 41/238 reads (17%) | called by mutect2, pindel, varscan2
- NIPAL1 | c.88_93del p.W30_C31del | In Frame Del (DEL) | VAF 36/165 reads (22%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.4282_4285del p.N1428Cfs*49 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- APIP | c.483A>G p.V161= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV99551667; called by muse, mutect2
- COP1 | c.927T>C p.D309= | Silent (SNP) | VAF 11/296 reads (4%) | catalogued as rs1276443286, COSV100443448; called by muse, mutect2
- DARS1 | c.327C>T p.N109= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99927634; called by muse, mutect2, varscan2
- DCAF4L2 | c.288C>T p.G96= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs763988457, COSV100150983; called by muse, mutect2
- DPH7 | c.369A>G p.E123= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99483588; called by muse, mutect2, varscan2
- EXT2 | c.1146A>G p.Q382= (on ENST00000343631; = p.Q415= on NM_000401.3) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV100640630; called by muse, mutect2, varscan2
- F2RL3 | c.996C>T p.N332= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99935308; called by muse, mutect2, varscan2
- GOLM2 | c.48C>A p.L16= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100247859; called by muse, mutect2, varscan2
- HIPK2 | c.936G>A p.L312= | Silent (SNP) | VAF 55/215 reads (26%) | catalogued as COSV100702302; called by muse, mutect2, varscan2
- KDM5C | c.3411G>T p.A1137= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV100948906, COSV100949278; called by muse, mutect2, varscan2
- LRRC47 | c.1662G>C p.R554= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100989324; called by muse, mutect2, varscan2
- TTN | c.12330C>T p.V4110= (on ENST00000591111; = p.V4064= on NM_003319.4) | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs551703401, COSV100617892; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF184 | c.618A>G p.K206= | Silent (SNP) | VAF 130/587 reads (22%) | catalogued as COSV99279740; called by muse, mutect2, varscan2
- PCDH7 | c.*2C>T | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SLC4A4 | c.254-85C>G | Intron (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99140487; called by muse, mutect2, varscan2
